Somatic mutation profile of tumor specimen C3N-01655-01 (aliquot CPT0121560005) from CPTAC case C3N-01655, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 64.1 years (23,430 days).
Specimen C3N-01655-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14f1c8f7-394d-4c42-b58d-81a5b99e3fe3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01655-31 (Blood Derived Normal), aliquot CPT0121600002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74639b44-a130-4057-9fd8-8b1046f39f86

The open-access MAF lists 88 somatic variants for this specimen: 64 protein-altering or splice-affecting, 17 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 17, Frame Shift Del 6, Splice Site 4, Intron 3, Nonsense Mutation 2, Frame Shift Ins 2, RNA 1, 5'Flank 1, In Frame Del 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALKBH5 | c.113_136del p.V38_A45del | In Frame Del (DEL) | VAF 58/270 reads (21%) | catalogued as rs779550198; called by mutect2, varscan2
- AQP10 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 68/241 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.468); catalogued as rs768207751, COSV61476104; called by muse, mutect2, varscan2
- DCAF6 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.472); catalogued as COSV56578642; called by muse, mutect2, varscan2
- DST | c.13330G>T p.A4444S (on ENST00000361203 / NM_001374722.1; = p.A2032S on NM_015548.5) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.171); catalogued as rs370851951; called by muse, mutect2, varscan2
- FCRL4 | c.758G>T p.R253I | Missense Mutation (SNP) | VAF 69/267 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.156); catalogued as COSV54859296; called by muse, mutect2, varscan2
- GRHPR | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 51/217 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs763059780; called by muse, mutect2, varscan2
- GRIN2B | c.4360C>A p.P1454T | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV74204952; called by muse, mutect2, varscan2
- HEPHL1 | c.2227G>C p.E743Q | Missense Mutation (SNP) | VAF 60/295 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV59889128; called by muse, mutect2, varscan2
- KRT16 | c.185G>A p.C62Y | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as rs367990963; called by muse, varscan2
- MED12 | c.2548C>T p.R850W | Missense Mutation (SNP) | VAF 89/202 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV61354399; called by muse, mutect2, varscan2
- MRPL37 | c.1033G>A p.V345M | Missense Mutation (SNP) | VAF 61/244 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs369065705; called by muse, mutect2, varscan2
- MYEF2 | c.373G>T p.G125C | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1176496943; called by muse, mutect2, varscan2
- PCSK1 | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 104/436 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV60734579; called by muse, mutect2, varscan2
- PCYT1A | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs748171719, COSV99492312; called by muse, mutect2
- PRR5 | c.898G>T p.G300C (on ENST00000336985 / NM_181333.4; = p.G291C on NM_015366.4) | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.461); catalogued as rs749045779; called by muse, mutect2, varscan2
- RFX2 | c.419G>T p.G140V | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as rs190511322; called by muse, mutect2, varscan2
- SLC38A7 | c.1174G>C p.G392R | Missense Mutation (SNP) | VAF 99/409 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV54703691; called by muse, mutect2, varscan2
- STYXL2 | c.1502G>A p.R501K | Missense Mutation (SNP) | VAF 67/241 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV54805364; called by muse, mutect2, varscan2
- UPK1A | c.581C>T p.T194M | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.589); catalogued as rs377645091; called by muse, mutect2, varscan2
- ZFP42 | c.926G>A p.G309E | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV58816841; called by muse, mutect2
- ZNF407 | c.5794G>A p.E1932K | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs752741639, COSV55245033; called by muse, mutect2, varscan2
- ZNF439 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs1198477254; called by muse, mutect2, varscan2
- ADPRH | c.761G>C p.R254T | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGT | c.863T>C p.M288T | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2
- AP000812.4 | c.221_222del p.S74Wfs*20 | Frame Shift Del (DEL) | VAF 32/171 reads (19%) | called by mutect2, pindel, varscan2
- AQP9 | c.836C>A p.T279K | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0); called by mutect2, varscan2
- ATF4 | c.450del p.K150Nfs*31 | Frame Shift Del (DEL) | VAF 30/127 reads (24%) | called by mutect2, pindel, varscan2
- ATP2B3 | c.3560A>G p.D1187G | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- BAG1 | c.424_431del p.A142Hfs*9 | Frame Shift Del (DEL) | VAF 30/146 reads (21%) | called by mutect2, pindel
- BUB1B | c.661_664del p.V221Hfs*6 | Frame Shift Del (DEL) | VAF 55/306 reads (18%) | called by mutect2, pindel*, varscan2*
- C1orf158 | c.169T>C p.F57L | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- CDYL2 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- CEP295NL | c.1107G>A p.M369I | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- CRLF2 | c.479G>T p.W160L | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DAOA | c.329_332dup p.Y111* | Frame Shift Ins (INS) | VAF 59/309 reads (19%) | called by mutect2, pindel, varscan2
- DLG2 | c.2131+1G>A p.X711_splice | Splice Site (SNP) | VAF 26/113 reads (23%) | called by muse, mutect2, varscan2
- DOCK9 | c.92A>G p.N31S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- EGLN2 | c.736C>A p.H246N | Missense Mutation (SNP) | VAF 72/296 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- FEM1A | c.618G>T p.K206N | Missense Mutation (SNP) | VAF 82/330 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR12 | c.50T>C p.L17S | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- IFNW1 | c.67G>C p.G23R | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); called by muse, varscan2
- INPP5A | c.978-15_987del p.X326_splice | Splice Site (DEL) | VAF 10/107 reads (9%) | called by mutect2, pindel
- KDM5C | c.515_522+5del p.X172_splice | Splice Site (DEL) | VAF 42/149 reads (28%) | called by mutect2, pindel, varscan2
- KRR1 | c.947A>T p.E316V | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- LRRC17 | c.1150_1151del p.Y384Qfs*10 | Frame Shift Del (DEL) | VAF 15/82 reads (18%) | called by mutect2, pindel, varscan2
- LTBP3 | c.337_338del p.C113Pfs*80 | Frame Shift Del (DEL) | VAF 40/236 reads (17%) | called by pindel, varscan2
- MAPK8IP3 | c.1928dup p.R644Afs*9 | Frame Shift Ins (INS) | VAF 50/208 reads (24%) | called by mutect2, pindel, varscan2
- MRPS14 | c.260T>G p.I87S | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NBPF1 | c.46A>C p.N16H | Missense Mutation (SNP) | VAF 75/388 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- NTSR2 | c.61G>C p.A21P | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PBRM1 | c.3388-25_3397del p.X1130_splice (on ENST00000296302 / NM_001366071.2; = p.X1105_splice on NM_018313.5) | Splice Site (DEL) | VAF 49/140 reads (35%) | called by mutect2, pindel
- POU6F2 | c.772C>T p.Q258* | Nonsense Mutation (SNP) | VAF 50/208 reads (24%) | called by muse, mutect2, varscan2
- SCYL1 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SESTD1 | c.768G>C p.E256D | Missense Mutation (SNP) | VAF 47/236 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SIGLEC1 | c.901G>T p.G301C | Missense Mutation (SNP) | VAF 52/246 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC12A1 | c.574T>C p.W192R | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPATA31A6 | c.742G>T p.G248C | Missense Mutation (SNP) | VAF 47/450 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- SSB | c.454G>T p.G152* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- TBCB | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 50/236 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TBCCD1 | c.840A>T p.K280N | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- TRIP6 | c.519G>T p.K173N | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- UBE3A | c.1235T>G p.L412R | Missense Mutation (SNP) | VAF 52/236 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- ZDHHC8 | c.456C>A p.F152L | Missense Mutation (SNP) | VAF 72/254 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- ZNF23 | c.1181G>T p.C394F | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCK5 | c.807G>A p.K269= | Silent (SNP) | VAF 53/269 reads (20%) | called by muse, mutect2, varscan2
- AQP9 | c.837A>G p.T279= | Silent (SNP) | VAF 26/110 reads (24%) | called by mutect2, varscan2
- D2HGDH | c.63G>A p.A21= | Silent (SNP) | VAF 46/180 reads (26%) | catalogued as rs1185597664; called by muse, mutect2, varscan2
- HAUS7 | c.576C>T p.C192= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as rs782052469, COSV57847639; called by muse, mutect2, varscan2
- INF2 | c.2628C>T p.F876= | Silent (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2
- MAP1A | c.6636C>A p.T2212= | Silent (SNP) | VAF 48/226 reads (21%) | called by muse, mutect2, varscan2
- MRGPRX3 | c.327C>T p.G109= | Silent (SNP) | VAF 50/160 reads (31%) | called by muse, mutect2, varscan2
- OPRD1 | c.915G>A p.A305= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as rs898272507, COSV52381237; called by muse, mutect2, varscan2
- P4HB | c.426C>T p.D142= | Silent (SNP) | VAF 38/184 reads (21%) | catalogued as rs776133642, COSV58941345; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDH15 | c.3714A>T p.V1238= | Silent (SNP) | VAF 45/175 reads (26%) | called by muse, mutect2, varscan2
- PLA2G4F | c.1878C>T p.F626= | Silent (SNP) | VAF 39/147 reads (27%) | catalogued as COSV101215246; called by muse, mutect2, varscan2
- SF3B2 | c.216G>A p.G72= | Silent (SNP) | VAF 69/287 reads (24%) | called by muse, mutect2, varscan2
- TGM6 | c.1188C>T p.N396= | Silent (SNP) | VAF 129/507 reads (25%) | catalogued as rs145029765; called by muse, mutect2, varscan2
- TMEM91 | c.453C>T p.G151= | Silent (SNP) | VAF 46/146 reads (32%) | catalogued as rs565098119, COSV55370737; called by muse, mutect2, varscan2
- UGT3A1 | c.597C>A p.G199= | Silent (SNP) | VAF 38/265 reads (14%) | called by muse, mutect2, varscan2
- VWA8 | c.3309A>G p.S1103= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs780738150; called by mutect2, varscan2
- ZNRF2 | c.141G>C p.G47= | Silent (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2
- CACNG4 | c.*799C>T | 3'UTR (SNP) | VAF 76/367 reads (21%) | catalogued as rs1481459676; called by muse, mutect2, varscan2
- FAM90A20P | n.1249C>G | RNA (SNP) | VAF 50/370 reads (14%) | catalogued as rs771909057; called by muse, mutect2, varscan2
- KLHL10 | c.195-15C>T | Intron (SNP) | VAF 20/96 reads (21%) | called by muse, mutect2, varscan2
- MEIS1 | c.1024+37A>G | Intron (SNP) | VAF 76/368 reads (21%) | catalogued as rs368702205; called by muse, mutect2, varscan2
- MMP14 | c.108+471C>T | Intron (SNP) | VAF 40/196 reads (20%) | catalogued as rs1423106828; called by muse, mutect2, varscan2
- UBE2Q2L | chr15:84172567 del C | 5'Flank (DEL) | VAF 12/81 reads (15%) | called by mutect2, varscan2
- ZNF571 | c.-10C>G | 5'UTR (SNP) | VAF 22/84 reads (26%) | called by muse, mutect2, varscan2
